Somatic mutation profile of tumor specimen ALCH-AE52-TTP1-A (aliquot ALCH-AE52-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AE52, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.2 years (27,451 days).
Specimen ALCH-AE52-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 404b107e-724a-4d02-8d71-c21620a721b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE52-NB1-A (Blood Derived Normal), aliquot ALCH-AE52-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3252bc60-bbee-4da5-be06-036d32b1ae6d

The open-access MAF lists 185 somatic variants for this specimen: 131 protein-altering or splice-affecting, 35 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 35, Intron 8, Nonsense Mutation 7, Frame Shift Del 7, RNA 4, Splice Site 3, 5'UTR 3, 3'UTR 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4159C>A p.R1387S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61254693; called by muse, mutect2, varscan2
- ADAMTS20 | c.5598G>T p.W1866C | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67131653; called by muse, mutect2, varscan2
- AL121899.2 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs745652639, COSV67350850; called by muse, mutect2, varscan2
- ANK3 | c.9688C>T p.R3230C | Missense Mutation (SNP) | VAF 50/558 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs145590509, COSV55052665; called by muse, mutect2
- ARMC4 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59456008; called by muse, mutect2
- BTAF1 | c.3940C>G p.Q1314E | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV99795070; called by muse, varscan2
- CA12 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs780478289, COSV51604208, COSV99457980; called by muse, mutect2, varscan2
- CACNA1C | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.674); catalogued as COSV59728299; called by muse, mutect2, varscan2
- CCNB3 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV52081242; called by muse, mutect2, varscan2
- CCNB3 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.034); catalogued as COSV52081569; called by muse, mutect2, varscan2
- CFAP65 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs144290052; called by muse, mutect2, varscan2
- COL22A1 | c.4369G>T p.E1457* | Nonsense Mutation (SNP) | VAF 41/193 reads (21%) | catalogued as COSV57322095; called by muse, mutect2, varscan2
- COL4A4 | c.3662C>A p.S1221Y | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61637190; called by muse, mutect2, varscan2
- DNAJA2 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 52/548 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as rs764110614, COSV57695631; called by muse, mutect2
- DPPA4 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV59512250; called by muse, varscan2
- DYSF | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs886043901; called by muse, mutect2, varscan2
- FAM171B | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV59001685; called by muse, mutect2
- FAM205A | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1564121115; called by muse, mutect2, varscan2
- FAM47A | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs747328997; called by muse, varscan2
- GLI2 | c.1796G>T p.S599I (on ENST00000361492 / NM_001374353.1; = p.S616I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1250165393; called by muse, varscan2
- H4C7 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs778903484; called by mutect2, varscan2
- HAAO | c.463A>T p.R155* | Nonsense Mutation (SNP) | VAF 78/275 reads (28%) | catalogued as rs866117467; called by muse, mutect2, varscan2
- HPS4 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100404731; called by muse, mutect2, varscan2
- L1CAM | c.3643G>T p.V1215L | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as COSV62827381; called by muse, mutect2, varscan2
- LDB2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1217816744, COSV58772553; called by muse, mutect2, varscan2
- NFATC2IP | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100297493; called by muse, mutect2, varscan2
- NUP210 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs552329643; called by muse, mutect2, varscan2
- OR4C6 | c.457C>G p.H153D | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58603793; called by muse, varscan2
- PCDH18 | c.3254G>T p.W1085L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV61271420; called by muse, mutect2, varscan2
- PCK1 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs766917599, COSV60126703; called by muse, mutect2, varscan2
- PLCL2 | c.2150G>T p.W717L (on ENST00000615277 / NM_001144382.2; = p.W591L on NM_015184.5) | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as COSV67625432; called by muse, mutect2, varscan2
- RTL3 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 70/474 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100329789; called by muse, mutect2, varscan2
- SEPHS2 | c.824_828del p.V275Dfs*? | Frame Shift Del (DEL) | VAF 42/361 reads (12%) | catalogued as rs771624369; called by pindel, varscan2
- SLITRK5 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 48/487 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs750617705; called by muse, mutect2
- TSG101 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV52650273; called by muse, mutect2, varscan2
- TTN | c.74995G>A p.E24999K (on ENST00000591111; = p.E17575K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/397 reads (11%) | PolyPhen benign (0.298); catalogued as COSV60062786; called by muse, mutect2, varscan2
- TTN | c.17221del p.R5741Afs*12 (on ENST00000591111; = p.R4814Afs*12 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/401 reads (16%) | catalogued as COSV60243237; called by mutect2, pindel, varscan2
- USH2A | c.13139C>T p.T4380I | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs533179037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR35 | c.1528A>G p.I510V (on ENST00000345530 / NM_001006657.2; = p.I499V on NM_020779.4) | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1265039923; called by muse, mutect2, varscan2
- ZBTB38 | c.2668G>A p.G890R | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1035766716; called by muse, mutect2, varscan2
- ZNF716 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70782789; called by muse, mutect2
- AAK1 | c.2180A>T p.K727M | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AATK | c.2731T>A p.S911T (on ENST00000326724 / NM_001080395.3; = p.S808T on NM_004920.2) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSM2B | c.1375A>C p.M459L | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM23 | c.1490C>G p.T497R | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADGRF5 | c.3182T>A p.L1061H | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AHNAK | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANKRD18A | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP35 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ARMC10 | c.888T>G p.H296Q | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.229); called by muse, mutect2
- ARMC8 | c.1553G>T p.R518L (on ENST00000469044 / NM_001363941.2; = p.R504L on NM_015396.6) | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATP1B4 | c.1012A>T p.N338Y (on ENST00000218008 / NM_001142447.3; = p.N334Y on NM_012069.5) | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCOR | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- C1QC | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CA7 | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1E | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CASK | c.2501T>A p.I834K (on ENST00000378163 / NM_001367721.1; = p.I829K on NM_003688.3) | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC175 | c.1791C>A p.N597K | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.685); called by muse, mutect2
- CD226 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CHRNG | c.461T>A p.V154D | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COG5 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CSMD3 | c.7430G>C p.S2477T (on ENST00000297405 / NM_001363185.1; = p.S2373T on NM_052900.3) | Missense Mutation (SNP) | VAF 113/527 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- DNAH8 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DNAJB8 | c.255C>A p.S85R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNLT3 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ELMO1 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- EVC2 | c.2464C>G p.Q822E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM47C | c.1622G>T p.S541I | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBH1 | c.754-2A>G p.X252_splice (on ENST00000362091 / NM_178150.3; = p.X303_splice on NM_032807.4) | Splice Site (SNP) | VAF 18/180 reads (10%) | called by muse, varscan2
- FERMT2 | c.2003A>G p.D668G | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHAD1 | c.3536C>G p.S1179* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | called by muse, varscan2
- FRMPD3 | c.4978T>C p.Y1660H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FRYL | c.4569del p.Q1524Nfs*5 | Frame Shift Del (DEL) | VAF 108/521 reads (21%) | called by mutect2, pindel, varscan2
- GABRG1 | c.952A>T p.T318S | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GART | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GCC1 | c.527del p.T176Ifs*18 | Frame Shift Del (DEL) | VAF 92/439 reads (21%) | called by mutect2, pindel, varscan2
- GPR75 | c.1271A>G p.H424R | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIA4 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5A | c.4565C>A p.P1522Q | Missense Mutation (SNP) | VAF 40/598 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2
- HOXA1 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HSPG2 | c.4141del p.Q1381Sfs*64 | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- ICE1 | c.6172G>T p.A2058S | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- JPH3 | c.1296C>A p.Y432* | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- KIF1C | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 17/277 reads (6%) | called by muse, mutect2
- KRTAP20-3 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.031); called by muse, varscan2
- LRRC8D | c.2264A>T p.Q755L | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAP2K6 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MAPKAPK3 | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2
- MXRA5 | c.7257G>T p.L2419F | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- NBEA | c.4466G>C p.R1489T | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.344); called by muse, mutect2
- NCOA7 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NLGN1 | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NMS | c.452T>C p.I151T | Missense Mutation (SNP) | VAF 21/608 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- NPHP1 | c.2096G>A p.G699D (on ENST00000393272 / NM_207181.4; = p.G700D on NM_000272.5) | Missense Mutation (SNP) | VAF 42/521 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR12D3 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR13C2 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- OR4C16 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, varscan2
- OR5J2 | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OTC | c.970T>G p.F324V | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- PAPPA | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDHAC1 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- PGD | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- PGLYRP2 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PHF10 | c.352A>T p.K118* | Nonsense Mutation (SNP) | VAF 30/160 reads (19%) | called by muse, varscan2
- PIK3C3 | c.1708-2A>T p.X570_splice | Splice Site (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- PLCL2 | c.2149T>C p.W717R (on ENST00000615277 / NM_001144382.2; = p.W591R on NM_015184.5) | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PLXNA3 | c.2596G>T p.G866C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R16B | c.1105T>A p.W369R | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PRDM5 | c.752A>C p.Q251P | Missense Mutation (SNP) | VAF 94/463 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PROS1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2
- PTCHD1 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RBM4 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- RELN | c.5824G>C p.D1942H | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- RUNX1T1 | c.1414del p.E472Sfs*7 (on ENST00000265814 / NM_001198628.1; = p.E445Sfs*7 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- SLC22A24 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SLC35G6 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1C1 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAF15 | c.265C>G p.Q89E (on ENST00000605844 / NM_139215.3; = p.Q86E on NM_003487.4) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- TRIM26 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TSHZ2 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- TTC5 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.89986G>A p.A29996T (on ENST00000591111; = p.A22572T on NM_003319.4) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TTN | c.64501C>A p.P21501T (on ENST00000591111; = p.P14077T on NM_003319.4) | Missense Mutation (SNP) | VAF 31/186 reads (17%) | PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- USH2A | c.15404C>A p.T5135N | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZFHX4 | c.9290C>A p.A3097D | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ZNF385D | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF451 | c.334del p.A112Lfs*27 | Frame Shift Del (DEL) | VAF 49/251 reads (20%) | called by mutect2, pindel, varscan2
- ZNF512 | c.937-1G>C p.X313_splice | Splice Site (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- ABCB6 | c.333C>G p.S111= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV54695858; called by muse, mutect2, varscan2
- ANO1 | c.1770C>T p.L590= | Silent (SNP) | VAF 63/155 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1185A>T p.L395= (on ENST00000395184 / NM_001025616.3; = p.L302= on NM_031305.3) | Silent (SNP) | VAF 50/189 reads (26%) | called by muse, mutect2, varscan2
- CCDC85A | c.366G>T p.V122= | Silent (SNP) | VAF 39/245 reads (16%) | called by muse, mutect2, varscan2
- CEACAM1 | c.1329G>A p.L443= | Silent (SNP) | VAF 77/407 reads (19%) | called by muse, mutect2, varscan2
- CPS1 | c.2151C>G p.A717= | Silent (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- DTHD1 | c.1704A>G p.G568= (on ENST00000456874; = p.G403= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- EXOC6 | c.1338C>T p.S446= | Silent (SNP) | VAF 19/291 reads (7%) | called by muse, mutect2
- FBXO40 | c.678C>T p.H226= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as rs769751719; called by muse, mutect2, varscan2
- FLRT2 | c.1326C>G p.L442= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs768723773, COSV58147383; called by muse, mutect2, varscan2
- GOLGA8G | c.1404C>T p.A468= | Silent (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- LAMTOR5 | c.243C>A p.G81= (on ENST00000602318 / NM_001382293.1; = p.G163= on NM_006402.3) | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- MDGA2 | c.1449G>C p.T483= (on ENST00000399232 / NM_001113498.2; = p.T185= on NM_182830.4) | Silent (SNP) | VAF 90/335 reads (27%) | catalogued as COSV62109259; called by muse, mutect2, varscan2
- NCOA2 | c.3942C>G p.G1314= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as rs1407144985; called by muse, mutect2, varscan2
- NOS2 | c.3213G>C p.V1071= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- OR56A4 | c.1008C>T p.H336= | Silent (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- PDGFC | c.153T>C p.T51= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PLXNA3 | c.2595G>T p.L865= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100860255; called by muse, mutect2, varscan2
- PREX2 | c.2838T>C p.S946= | Silent (SNP) | VAF 30/634 reads (5%) | catalogued as COSV55789196; called by muse, mutect2
- RABEP1 | c.1611C>T p.S537= | Silent (SNP) | VAF 65/286 reads (23%) | called by muse, mutect2, varscan2
- SHCBP1L | c.1755T>C p.Y585= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as rs1243111327; called by muse, mutect2, varscan2
- SMARCC1 | c.1503C>T p.N501= | Silent (SNP) | VAF 38/247 reads (15%) | called by muse, mutect2, varscan2
- SPNS3 | c.684C>T p.P228= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, varscan2
- SPTBN1 | c.4125G>T p.R1375= | Silent (SNP) | VAF 71/452 reads (16%) | called by muse, mutect2, varscan2
- SSTR2 | c.435C>T p.V145= | Silent (SNP) | VAF 49/307 reads (16%) | called by muse, mutect2, varscan2
- SYN1 | c.1656G>A p.P552= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs975694930; called by muse, mutect2, varscan2
- TACC3 | c.2385C>A p.A795= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as COSV100508733; called by muse, mutect2, varscan2
- TM9SF4 | c.12G>C p.A4= | Silent (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.7950C>T p.G2650= (on ENST00000591111; = p.G2604= on NM_003319.4) | Silent (SNP) | VAF 57/242 reads (24%) | catalogued as rs773756480; called by muse, mutect2, varscan2
- VSIR | c.198G>T p.V66= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- WDFY1 | c.576C>T p.I192= | Silent (SNP) | VAF 62/238 reads (26%) | called by muse, mutect2, varscan2
- ZDHHC22 | c.600C>A p.A200= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7866A>G p.E2622= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV51477829; called by muse, mutect2, varscan2
- ZIM3 | c.582C>A p.P194= | Silent (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- ZNF253 | c.732T>C p.T244= | Silent (SNP) | VAF 24/237 reads (10%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847288 C>G | 5'Flank (SNP) | VAF 68/367 reads (19%) | called by muse, mutect2, varscan2
- C11orf40 | n.479A>T | RNA (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+434G>C | Intron (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- DCAF10 | chr9:37800684 C>T | 5'Flank (SNP) | VAF 12/114 reads (11%) | catalogued as rs1490675488; called by muse, mutect2
- DEFB121 | n.201T>A | RNA (SNP) | VAF 41/261 reads (16%) | called by muse, mutect2, varscan2
- DEPDC1 | c.911-398G>A | Intron (SNP) | VAF 20/312 reads (6%) | catalogued as COSV100920314; called by muse, mutect2
- ELP6 | c.323+934G>T | Intron (SNP) | VAF 66/344 reads (19%) | called by muse, mutect2, varscan2
- FAM161A | c.*74A>C | 3'UTR (SNP) | VAF 59/237 reads (25%) | called by muse, mutect2, varscan2
- FOXA1 | c.-37A>G | 5'UTR (SNP) | VAF 97/299 reads (32%) | catalogued as rs997431688; called by muse, mutect2, varscan2
- GABRA2 | c.-7G>C | 5'UTR (SNP) | VAF 21/314 reads (7%) | catalogued as rs201399644; called by muse, mutect2
- IGKV2D-24 | c.-22C>T | 5'UTR (SNP) | VAF 66/368 reads (18%) | called by muse, mutect2, varscan2
- KLC1 | c.*10349T>C | 3'UTR (SNP) | VAF 96/613 reads (16%) | called by muse, mutect2, varscan2
- LMBR1L | c.72+666A>T | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- LRP1B | c.13247+923G>A | Intron (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2, varscan2
- MIR526A2 | n.11A>G | RNA (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- NXPE1 | c.834-926C>T | Intron (SNP) | VAF 7/56 reads (13%) | catalogued as rs1464955166; called by muse, mutect2, varscan2
- RPLP0P2 | n.1129C>G | RNA (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- SMAD3 | c.207-21971G>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- ULK3 | c.1288-17A>T | Intron (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
